CPTAC case C3N-03430 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d46f586-4fa3-455a-8fd5-c87afc57d315

Demographics
Sex at birth: female; Race: white; Year of birth: 1963; Vital status: Dead; Days to death: 39 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 54.6 years (19,939 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic M: MX; Tumor grade: G2; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 39 days; Days to last follow up: 30 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: Yes; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 30 days; Disease response: Progressive Disease; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 50 kg; Height: 164 cm; BMI: 18.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 7.3; Cigarettes per day: 5; Tobacco smoking onset year: 1988; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 34.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03430-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 177 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03430-22: Section location: Head; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3N-03430-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
